Somatic mutation profile of tumor specimen TARGET-20-PANVGP-09A (aliquot TARGET-20-PANVGP-09A-01D) from TARGET case TARGET-20-PANVGP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.6 years (4,950 days).
Specimen TARGET-20-PANVGP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff03b454-36d7-4d83-85c1-d5d3280f1305.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANVGP-14A (Bone Marrow Normal), aliquot TARGET-20-PANVGP-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cd36e93-09c6-4a17-a417-7139a56dbf7f

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS2 | c.35A>G p.H12R | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs1238233777, COSV55328734; called by muse, mutect2, varscan2
- ECHDC2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs757347862, COSV64301413; called by muse, mutect2, varscan2
- HS3ST5 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs373398789; called by muse, mutect2, varscan2
- POP4 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.136); catalogued as COSV55677535; called by muse, mutect2, varscan2
- POTEG | c.314G>T p.C105F | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); catalogued as rs758072088; called by muse, mutect2, varscan2
- PTPRF | c.448_449insTT p.R150Lfs*27 | Frame Shift Ins (INS) | VAF 52/142 reads (37%) | catalogued as COSV63445852; called by mutect2, pindel*, varscan2
- SNRPA | c.128T>A p.I43N | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54682970; called by muse, mutect2, varscan2
- TMEM174 | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.912); catalogued as COSV57113790; called by muse, mutect2, varscan2
- USP48 | c.808T>A p.C270S | Missense Mutation (SNP) | VAF 140/359 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57614997; called by muse, mutect2, varscan2
- ZNF91 | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 122/300 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.238); catalogued as COSV100322403, COSV56087165; called by muse, mutect2, varscan2
- SPON1 | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, varscan2
- PIEZO1 | c.828G>A p.P276= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1280947499, COSV56343956; called by muse, mutect2, varscan2
- SLC16A9 | c.801G>A p.T267= | Silent (SNP) | VAF 90/245 reads (37%) | catalogued as rs748281198, COSV68099268; called by muse, mutect2
- SUGP1 | c.1734C>T p.G578= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as rs776660490, COSV55920974; called by muse, mutect2, varscan2
